Somatic mutation profile of tumor specimen MMRF_1671_2_BM_CD138pos (aliquot MMRF_1671_2_BM_CD138pos_T1_KHS5U_L09497) from MMRF case MMRF_1671, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.6 years (25,073 days).
Specimen MMRF_1671_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2e43118-d8a9-414b-9da5-9f015edd1ebd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1671_4_PB_WBC (Blood Derived Normal), aliquot MMRF_1671_4_PB_WBC_C3_KHS5U_L15743; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19fa7dd7-3851-4141-9219-dd1139365106

The open-access MAF lists 80 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 12, Silent 11, Intron 8, Splice Site 5, Nonsense Mutation 4, 5'UTR 3, 3'Flank 3, Frame Shift Del 2, 5'Flank 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP7B1 | c.1354C>T p.R452* | Nonsense Mutation (SNP) | VAF 74/193 reads (38%) | catalogued as rs769676029, COSV59592240; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ELANE | c.597+1G>A p.X199_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as rs1555710005, CS091635, CS112156, CS993231; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs794728325, CM091205, CM091206, CS013965, COSV57313335; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CSPG5 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751401533; called by muse, mutect2, varscan2
- DCHS1 | c.4252C>T p.R1418W | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs749199604; called by muse, mutect2, varscan2
- DDX60 | c.1163A>G p.Y388C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs778995813; called by muse, mutect2, varscan2
- EIF3E | c.661_664del p.V221Sfs*36 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs762916048; called by pindel, varscan2
- EPHA4 | c.1135C>A p.P379T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as rs1346215997; called by muse, mutect2, varscan2
- EPX | c.1121-1G>A p.X374_splice | Splice Site (SNP) | VAF 29/69 reads (42%) | catalogued as COSV56598256; called by muse, mutect2, varscan2
- GPR142 | c.1254C>G p.S418R | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs368187784; called by muse, mutect2, varscan2
- HIVEP3 | c.3382G>A p.V1128I | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs540145704, COSV56014541; called by muse, mutect2, varscan2
- HMX1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1336325306; called by muse, mutect2, varscan2
- IGKV4-1 | c.68T>A p.V23E | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs772165006; called by mutect2, varscan2
- IGLV3-1 | c.146A>T p.K49I | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs61731694; called by muse, varscan2
- KRT3 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546099163, COSV58815743; called by muse, varscan2
- LHX9 | c.1040C>A p.S347* | Nonsense Mutation (SNP) | VAF 10/351 reads (3%) | catalogued as COSV100435640; called by muse, mutect2
- NCAPH2 | c.1757C>T p.T586M | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752146981, COSV52687158; called by muse, mutect2, varscan2
- NCOA1 | c.4155+1G>T p.X1385_splice | Splice Site (SNP) | VAF 50/119 reads (42%) | catalogued as rs769235879; called by muse, mutect2, varscan2
- SPATA31E1 | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs1184361142; called by muse, mutect2, varscan2
- TEP1 | c.3867+2T>G p.X1289_splice | Splice Site (SNP) | VAF 68/165 reads (41%) | catalogued as COSV52993602; called by muse, mutect2, varscan2
- ZNF286A | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV101224868; called by muse, mutect2, varscan2
- ABCB5 | c.3241G>A p.A1081T (on ENST00000404938 / NM_001163941.2; = p.A636T on NM_178559.6) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.691); called by muse, mutect2
- AHNAK | c.10207T>A p.F3403I | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CDK13 | c.403A>T p.S135C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.621); called by muse, mutect2
- CFAP47 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- DKK2 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- FBXO30 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELZ2 | c.1964_1990del p.R655_H663del (on ENST00000467148 / NM_001037335.2; = p.R86_H94del on NM_033405.3) | In Frame Del (DEL) | VAF 22/84 reads (26%) | called by mutect2, pindel
- IGHV2-70D | c.145A>C p.S49R | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, varscan2
- IGSF21 | c.125T>A p.V42E | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- KDM3B | c.5187T>G p.N1729K | Missense Mutation (SNP) | VAF 92/215 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LKAAEAR1 | c.288G>A p.W96* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- NKAP | c.1115A>G p.Q372R | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- NUFIP2 | c.843_849del p.Y282Lfs*27 | Frame Shift Del (DEL) | VAF 58/131 reads (44%) | called by mutect2, pindel, varscan2
- QRFPR | c.738A>T p.R246S | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- RAP1GAP | c.1000-1G>A p.X334_splice | Splice Site (SNP) | VAF 5/101 reads (5%) | called by muse, mutect2
- RHEBL1 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RYR1 | c.3163C>T p.P1055S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- STK32A | c.856T>G p.W286G | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRIM9 | c.2042C>A p.P681H | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP45 | c.492C>T p.I164= | Silent (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- CPA4 | c.1014G>A p.A338= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs577880214; called by muse, mutect2, varscan2
- CRACDL | c.607C>T p.L203= | Silent (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- EVC | c.1074C>T p.C358= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs921573510, COSV53832080; called by muse, mutect2, varscan2
- INIP | c.21A>G p.G7= | Silent (SNP) | VAF 14/236 reads (6%) | catalogued as rs1364659546; called by muse, mutect2
- KCNB2 | c.447C>T p.N149= | Silent (SNP) | VAF 119/299 reads (40%) | catalogued as rs755305477, COSV101578734, COSV73048698; called by muse, mutect2, varscan2
- NTRK2 | c.2103G>T p.V701= (on ENST00000323115 / NM_001369534.1; = p.V717= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/162 reads (36%) | called by muse, mutect2, varscan2
- PEMT | c.282C>T p.L94= | Silent (SNP) | VAF 69/175 reads (39%) | catalogued as rs753328073; called by muse, mutect2, varscan2
- SYNC | c.186G>A p.E62= | Silent (SNP) | VAF 93/254 reads (37%) | catalogued as COSV65131234; called by muse, mutect2, varscan2
- TTN | c.99648G>A p.L33216= (on ENST00000591111; = p.L25792= on NM_003319.4) | Silent (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- ZNF510 | c.54C>T p.G18= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV56296644; called by muse, mutect2, varscan2
- ADCY1 | c.1605+2212C>G | Intron (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- AL132796.2 | n.648C>G | RNA (SNP) | VAF 69/156 reads (44%) | called by muse, mutect2, varscan2
- ANTXRL | c.1045-547C>T | Intron (SNP) | VAF 15/89 reads (17%) | catalogued as rs1166629925; called by muse, mutect2, varscan2
- BNIPL | c.*341C>T | 3'UTR (SNP) | VAF 16/81 reads (20%) | catalogued as rs748564594; called by muse, mutect2
- CCDC68 | chr18:54903648 G>T | 3'Flank (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- CHRM2 | chr7:137018802 G>T | 3'Flank (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- CLPTM1 | c.72+148C>T | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- DSC2 | c.*174C>A | 3'UTR (SNP) | VAF 30/76 reads (39%) | called by mutect2, varscan2
- FGF12 | c.-732G>A | 5'UTR (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- GET4 | c.235-54C>T | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2
- GNG4 | c.*1177G>A | 3'UTR (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- KIAA1109 | c.*408A>T | 3'UTR (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- NIBAN1 | c.*3919T>C | 3'UTR (SNP) | VAF 229/413 reads (55%) | called by muse, mutect2, varscan2
- PAN2 | c.*631G>A | 3'UTR (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2, varscan2
- PCDH15 | c.*229G>A | 3'UTR (SNP) | VAF 43/88 reads (49%) | catalogued as rs974421099; called by muse, mutect2, varscan2
- PCK1 | c.406+139T>A | Intron (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2
- POR | c.-5+11T>A | Intron (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- POU2F2 | chr19:42089640 C>T | 3'Flank (SNP) | VAF 62/126 reads (49%) | called by muse, mutect2, varscan2
- PTPN13 | c.4149+15G>A | Intron (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- RFT1 | c.-8C>T | 5'UTR (SNP) | VAF 51/103 reads (50%) | catalogued as rs766568297; called by muse, mutect2, varscan2
- RPL31 | c.*106C>T | 3'UTR (SNP) | VAF 159/394 reads (40%) | called by muse, mutect2, varscan2
- TAFA5 | c.*1701G>A | 3'UTR (SNP) | VAF 27/75 reads (36%) | catalogued as rs1241119143; called by muse, mutect2, varscan2
- TMEM185A | c.*847T>C | 3'UTR (SNP) | VAF 47/87 reads (54%) | called by muse, mutect2, varscan2
- TMSB4X | c.-78T>C | 5'UTR (SNP) | VAF 91/109 reads (83%) | called by muse, mutect2, varscan2
- TRERF1 | c.*2994C>A | 3'UTR (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- UNC5C | c.775+2033A>C | Intron (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- VCP | chr9:35072721 T>C | 5'Flank (SNP) | VAF 74/167 reads (44%) | catalogued as rs527975908; called by muse, mutect2, varscan2
- ZFC3H1 | c.*239C>T | 3'UTR (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
